RC case RC-B65J — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e9b2fdcf-b562-4a6f-97f1-d0a461acec3e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1977; Vital status: Alive.

Diagnoses (1)
1. Hepatosplenic T-cell lymphoma: ICD-O-3 morphology code: 9716/3; ICD-10 code: C84; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 39.1 years (14,293 days); Year of diagnosis: 2016; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Fever / Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Bone marrow / Liver / Peripheral blood / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide + Ifosfamide; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ICE; Days to treatment start: -10 days; Days to treatment end: 52 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -10 days; Treatment outcome: Complete Response; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 83 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Days to follow up: 41 days; Disease response: Tumor Free.
- Day 2,013 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 2,253 days (6.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 437 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus: Negative [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Crohn's Disease / Other / Anemia.
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Anti-TNF Therapy.
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Prednisone.
- Timepoint category: Initial Diagnosis; Weight: 55.2 kg; Height: 162 cm; BMI: 21.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B65J-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B65J-TMP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
